Somatic mutation profile of tumor specimen TCGA-CQ-5332-01A (aliquot TCGA-CQ-5332-01A-01D-1683-08) from TCGA case TCGA-CQ-5332, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 87.7 years (32,032 days).
Specimen TCGA-CQ-5332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e11f5c1-78c9-4317-bdd3-cd2034862e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5332-10A (Blood Derived Normal), aliquot TCGA-CQ-5332-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7733102-14fb-45e4-a83e-2601792225fe

The open-access MAF lists 153 somatic variants for this specimen: 119 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 33, Nonsense Mutation 5, Frame Shift Del 4, Splice Region 2, Intron 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1558G>C p.D520H (on ENST00000281708 / NM_001349798.2; = p.D440H on NM_018315.5) | Missense Mutation (SNP) | VAF 109/157 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895090, COSV55923112, COSV55961967; called by muse, mutect2, varscan2
- MAP2K2 | c.171T>G p.F57L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1057519910, CM083721, COSV53569171, COSV99502205; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 36/46 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs141121285; called by muse, mutect2, varscan2
- ADAMTS18 | c.3143G>T p.C1048F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99271864; called by muse, mutect2, varscan2
- ADCY8 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs373225005, COSV53900962; called by muse, mutect2, varscan2
- AKAP3 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 62/104 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs545087055, COSV57414658, COSV57420537; called by muse, mutect2, varscan2
- ATP8B4 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV52718751; called by mutect2, varscan2
- BRD1 | c.2515G>A p.G839S (on ENST00000216267 / NM_001349940.1; = p.G970S on NM_001304808.3) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs139682438; called by muse, varscan2
- CAMTA1 | c.2312A>T p.N771I | Missense Mutation (SNP) | VAF 128/184 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100347859; called by muse, mutect2, varscan2
- CDH7 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763799602, COSV59889928; called by muse, mutect2, varscan2
- CNBD1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV101572852; called by muse, mutect2, varscan2
- CNOT1 | c.5468G>A p.R1823H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1412088237, COSV55323116; called by muse, mutect2
- COL22A1 | c.2681A>T p.Q894L | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as COSV100277372; called by muse, mutect2, varscan2
- COX16 | c.183A>G p.I61M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV101112160; called by muse, mutect2, varscan2
- CPAMD8 | c.1801G>C p.V601L (on ENST00000651564; = p.V554L on NM_015692.5) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV99359163; called by muse, mutect2, varscan2
- DENND1C | c.1644C>A p.S548R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as COSV100375243; called by muse, mutect2, varscan2
- DGKK | c.3105A>T p.R1035S | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101052940; called by muse, mutect2, varscan2
- DIP2A | c.2846G>T p.G949V | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100595541; called by muse, mutect2, varscan2
- DNAH8 | c.7963C>T p.H2655Y | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59479793; called by muse, mutect2, varscan2
- DYNC2I2 | c.1595C>A p.A532E | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100823394, COSV63989853; called by muse, mutect2, varscan2
- DYSF | c.4128G>T p.K1376N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50579186, COSV99245641; called by muse, mutect2
- DYSF | c.4129A>C p.N1377H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99245643; called by muse, mutect2
- EDARADD | c.94G>A p.D32N (on ENST00000334232 / NM_145861.4; = p.D22N on NM_080738.4) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100512650; called by muse, mutect2, varscan2
- EPDR1 | c.391T>A p.S131T | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99554311; called by muse, mutect2, varscan2
- FAM47C | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs782736285, COSV100792410; called by muse, mutect2, varscan2
- GALNT8 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1228064197, COSV52897868; called by muse, mutect2, varscan2
- GRIA2 | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV52386606; called by muse, mutect2, varscan2
- GRIK4 | c.1325A>G p.D442G | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV101483573, COSV70799298; called by muse, mutect2, varscan2
- GSAP | c.1237T>A p.L413I | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99990068; called by muse, mutect2, varscan2
- H2BC21 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100479765; called by muse, mutect2, varscan2
- H4C11 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs758581420, COSV100747976; called by muse, varscan2
- HERC2 | c.9973A>C p.T3325P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV99872171; called by muse, varscan2
- HS6ST3 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs562169523, COSV65001095; called by muse, mutect2, varscan2
- HUWE1 | c.3179G>A p.G1060D | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99471354; called by muse, mutect2, varscan2
- IGLV2-14 | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.062); catalogued as rs746026023; called by muse, varscan2
- IL16 | c.2290G>A p.A764T (on ENST00000302987 / NM_172217.5; = p.A63T on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs757579432, COSV57263028; called by muse, mutect2, varscan2
- IL21R | c.1500C>A p.S500R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100559955; called by muse, mutect2, varscan2
- IMPA1 | c.567G>C p.G189= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as COSV56271232, COSV99808856; called by muse, mutect2, varscan2
- INO80D | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.998); catalogued as COSV101305808; called by muse, mutect2, varscan2
- ITGB1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV56480972; called by muse, mutect2, varscan2
- KCNJ1 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100131287; called by muse, mutect2, varscan2
- KCNMB1 | c.314A>T p.Y105F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV51131679; called by muse, varscan2
- KCTD3 | c.1085A>T p.D362V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99379002, COSV99379049; called by muse, mutect2, varscan2
- KCTD3 | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV52070566, COSV99379052; called by muse, mutect2, varscan2
- KLF12 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV100888440; called by muse, mutect2, varscan2
- KLF15 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955112; called by muse, mutect2, varscan2
- KLHL31 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV100911757; called by muse, mutect2, varscan2
- LAMA1 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as rs570589347, COSV101055690; called by muse, mutect2, varscan2
- LINGO4 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749018718, COSV59092368, COSV59094909; called by muse, mutect2, varscan2
- LMO7 | c.2477A>G p.E826G (on ENST00000357063; = p.E507G on NM_005358.5) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100412803; called by muse, mutect2, varscan2
- LMOD2 | c.1145G>C p.R382T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV101505434, COSV71755521; called by muse, mutect2, varscan2
- LRP1 | c.7985G>T p.R2662L | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.075); catalogued as rs146710883, COSV54518139; called by muse, mutect2, varscan2
- LRRC36 | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99338557; called by muse, mutect2, varscan2
- LTBP1 | c.2895C>G p.D965E (on ENST00000404816 / NM_206943.4; = p.D639E on NM_000627.4) | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV63194870; called by muse, mutect2, varscan2
- MAP7D1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748047465, COSV100294338; called by muse, mutect2, varscan2
- NDST4 | c.1097T>A p.L366H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV99995991; called by muse, mutect2, varscan2
- NEXMIF | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766391935, COSV50083099; called by muse, mutect2, varscan2
- NKX2-2 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV101010527; called by muse, mutect2, varscan2
- NLRC4 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.988); catalogued as rs770290700, COSV61593264; called by muse, mutect2, varscan2
- NPAP1 | c.924del p.C309Vfs*81 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | catalogued as COSV100275948; called by mutect2, pindel, varscan2
- NPBWR2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370307704; called by muse, mutect2, varscan2
- NRXN1 | c.3647G>A p.R1216H | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765200132, COSV60486467, COSV60508284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4K15 | c.338G>A p.R113H (on ENST00000305051; = p.R89H on NM_001005486.1) | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139377821, COSV100520989; called by muse, mutect2, varscan2
- OR5AR1 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100265616; called by muse, mutect2, varscan2
- OR5L2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV101004275, COSV65725392; called by muse, mutect2, varscan2
- OR8B8 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.975); catalogued as rs144609364; called by muse, mutect2, varscan2
- PAH | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100187820; called by muse, mutect2
- PAPPA | c.1651T>C p.Y551H | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100073457; called by muse, mutect2, varscan2
- PARP12 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693937; called by muse, mutect2, varscan2
- PCDHA2 | c.2256G>T p.Q752H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV100973735; called by muse, mutect2, varscan2
- PCLO | c.8812G>C p.A2938P | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV100429844; called by muse, mutect2
- PGAP6 | c.1755G>A p.T585= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as rs778749729, COSV99170620, COSV99170774; called by muse, mutect2, varscan2
- PLA2G4F | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1349195930, COSV99300462; called by muse, mutect2, varscan2
- PLRG1 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT tolerated (0.52); PolyPhen benign (0.268); catalogued as COSV100123057; called by muse, mutect2, varscan2
- PLXNB2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779647430, COSV100833894; called by muse, mutect2, varscan2
- PRSS37 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1359639627, COSV100633821; called by muse, mutect2, varscan2
- PSG7 | c.614T>A p.F205Y | Missense Mutation (SNP) | VAF 183/485 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV101343215; called by muse, mutect2, varscan2
- RAG2 | c.1543A>C p.T515P | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV100271177; called by muse, mutect2, varscan2
- RASGEF1B | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as COSV100020911; called by muse, mutect2, varscan2
- RBFOX1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768320837, COSV100300549; called by muse, mutect2, varscan2
- RFC5 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969800; called by muse, mutect2, varscan2
- RIMS2 | c.3184A>T p.R1062W (on ENST00000666250 / NM_001348490.2; = p.R870W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99165389; called by muse, mutect2, varscan2
- RNF213 | c.13921G>A p.V4641M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs751824353, COSV100300117; called by muse, mutect2, varscan2
- RYR1 | c.11142-1G>A p.X3714_splice | Splice Site (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100615227; called by muse, mutect2
- SACS | c.12845G>C p.G4282A | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101207277; called by muse, mutect2, varscan2
- SAMD14 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99142932; called by muse, mutect2, varscan2
- SEMA5A | c.2876A>G p.E959G | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV101227566; called by muse, mutect2, varscan2
- SERINC2 | c.55G>A p.G19S (on ENST00000373709 / NM_178865.5; = p.G23S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.818); catalogued as rs1323747003, COSV101036780; called by muse, mutect2, varscan2
- SETBP1 | c.3117C>G p.S1039R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99952605; called by muse, mutect2, varscan2
- SIPA1L2 | c.4470G>C p.E1490D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs750413617, COSV53388805; called by muse, mutect2, varscan2
- SLC2A2 | c.1193A>T p.Y398F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.599); catalogued as COSV100049197; called by muse, mutect2
- SLC35F1 | c.696T>G p.I232M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100837691; called by muse, mutect2, varscan2
- SLC39A3 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs572760698, COSV54117464; called by muse, mutect2, varscan2
- SLC4A3 | c.2209C>A p.L737M | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT tolerated (0.42); PolyPhen benign (0.206); catalogued as COSV99812646; called by muse, mutect2, varscan2
- SLCO1B3 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV99681163; called by muse, mutect2, varscan2
- SNRNP200 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60488787; called by muse, mutect2, varscan2
- STK32B | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99284929; called by muse, mutect2
- TC2N | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.249); catalogued as COSV100562841, COSV100562866; called by muse, mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 38/283 reads (13%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TLE1 | c.1853del p.G618Efs*69 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as COSV64721236; called by mutect2, pindel, varscan2
- TP53RK | c.671G>C p.S224T | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.245); catalogued as COSV100927746; called by muse, mutect2, varscan2
- TRPV6 | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100844215; called by muse, mutect2, varscan2
- UBXN4 | c.804A>G p.I268M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs775866584, COSV99738868; called by muse, mutect2, varscan2
- UHRF2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 43/76 reads (57%) | catalogued as COSV99436373; called by muse, mutect2, varscan2
- UNC79 | c.5377G>C p.D1793H (on ENST00000393151 / NM_001346218.2; = p.D1616H on NM_020818.5) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV99826707; called by muse, mutect2, varscan2
- WEE2 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV101285149; called by muse, mutect2
- XPO1 | c.1607A>C p.N536T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101294181; called by muse, mutect2, varscan2
- ZMYM1 | c.2650A>G p.I884V | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1305289281, COSV100720932, COSV63251622; called by muse, mutect2, varscan2
- ZNF112 | c.1642A>C p.T548P (on ENST00000337401 / NM_001083335.2; = p.T542P on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201811934, COSV100495608; called by muse, mutect2
- ZNF180 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.094); catalogued as rs375641920, COSV99659706; called by muse, mutect2, varscan2
- ZNF354A | c.1673C>G p.T558S | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as COSV100234410; called by muse, mutect2, varscan2
- ZNF549 | c.741T>A p.Y247* (on ENST00000376233 / NM_001199295.2; = p.Y234* on NM_153263.2) | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV99558439; called by muse, mutect2, varscan2
- ZNF549 | c.742A>G p.K248E (on ENST00000376233 / NM_001199295.2; = p.K235E on NM_153263.2) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53724106, COSV99558442; called by muse, varscan2
- ZNF569 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV100386291, COSV100386379; called by muse, mutect2, varscan2
- CCL3L3 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- KIAA0753 | c.2746_2762del p.E916Qfs*7 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- NOC3L | c.2103dup p.P702Sfs*17 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel
- UHRF1BP1L | c.3828_3830del p.F1277del | In Frame Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.3633C>T p.Y1211= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs367839151, COSV56979580; called by muse, mutect2, varscan2
- ADAP2 | c.246C>T p.N82= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100437199; called by muse, mutect2, varscan2
- CAPRIN2 | c.1584A>G p.S528= | Silent (SNP) | VAF 71/273 reads (26%) | catalogued as COSV99195457; called by muse, mutect2, varscan2
- CCNB3 | c.2685T>G p.S895= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99328759; called by muse, mutect2, varscan2
- CDH4 | c.1224C>T p.T408= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs770671856, COSV100848632; called by muse, mutect2, varscan2
- CENPF | c.8040C>T p.C2680= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100871613; called by muse, mutect2, varscan2
- CRACD | c.2844C>T p.H948= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs754752604, COSV99948925; called by muse, mutect2, varscan2
- CYP2B6 | c.459G>A p.L153= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100137415, COSV57844980; called by muse, mutect2, varscan2
- ECRG4 | c.156C>T p.A52= | Silent (SNP) | VAF 78/206 reads (38%) | catalogued as rs962297240, COSV53002063, COSV99430276; called by muse, mutect2, varscan2
- EDRF1 | c.3226C>T p.L1076= (on ENST00000356792 / NM_001202438.2; = p.L1042= on NM_015608.2) | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV100523357; called by muse, mutect2, varscan2
- FPGS | c.264G>T p.L88= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV100948791; called by muse, mutect2, varscan2
- IGSF9 | c.714C>T p.V238= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100829607; called by muse, mutect2, varscan2
- ITGA5 | c.1524A>T p.P508= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV53219112; called by muse, mutect2, varscan2
- KRT81 | c.54C>T p.C18= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs770430502, COSV59808881; called by muse, mutect2, varscan2
- LRRK2 | c.2655T>C p.S885= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs897809290, COSV100109667; called by muse, mutect2, varscan2
- MYH4 | c.465C>T p.I155= | Silent (SNP) | VAF 67/185 reads (36%) | catalogued as rs751453116, COSV55112819, COSV99700740; called by muse, mutect2, varscan2
- NRAP | c.1449C>T p.I483= (on ENST00000359988 / NM_001322945.2; = p.I448= on NM_006175.4) | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as rs141308047; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCBP2 | c.177C>T p.I59= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV100827533; called by muse, mutect2, varscan2
- PCNX2 | c.669C>T p.L223= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV99266740; called by muse, mutect2, varscan2
- PDE4D | c.93C>T p.R31= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as rs375580342; called by muse, mutect2, varscan2
- PREX1 | c.3126C>T p.G1042= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100906138, COSV64250546; called by muse, mutect2, varscan2
- PRKACG | c.951G>A p.P317= | Silent (SNP) | VAF 47/71 reads (66%) | catalogued as rs759690621, COSV99598451; called by muse, mutect2, varscan2
- PTPRB | c.3543G>T p.G1181= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99716601; called by muse, mutect2
- SACS | c.2271C>G p.G757= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV101207278; called by muse, mutect2, varscan2
- SLC2A2 | c.1191T>C p.S397= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100049199; called by muse, mutect2
- SPTB | c.2028G>A p.Q676= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs781709677, COSV101072025; called by muse, mutect2, varscan2
- SUCO | c.1596T>G p.T532= | Silent (SNP) | VAF 74/198 reads (37%) | catalogued as COSV99742402; called by muse, mutect2, varscan2
- TECTA | c.3096G>A p.T1032= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs753223458, COSV50702782; called by muse, mutect2, varscan2
- TNS3 | c.3243C>T p.H1081= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1322003440, COSV100235252; called by muse, mutect2, varscan2
- TRAPPC13 | c.444G>A p.V148= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV99198858; called by muse, mutect2, varscan2
- TRHDE | c.1419T>C p.G473= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as rs755051819, COSV99669972; called by muse, mutect2, varscan2
- ZIC4 | c.141C>T p.H47= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV67171426; called by muse, mutect2, varscan2
- ZNF569 | c.1191T>A p.L397= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100386378; called by muse, mutect2, varscan2
- TTN | c.10360+1718C>T | Intron (SNP) | VAF 198/254 reads (78%) | catalogued as COSV100602702; called by muse, mutect2, varscan2
